Gene-level copy-number profile of specimen HCM-BROD-0957-C34-85A from HCMI case HCM-BROD-0957-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 42.7 years (15,582 days).
Specimen HCM-BROD-0957-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 92db7f56-8191-432f-9d7d-776b93145246.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0957-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/70b1907f-94ee-4bb6-bf4b-f9e20a5d0c2a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,126; copy number 2: 13,023; copy number 3: 22,463; copy number 4: 14,731; copy number 5: 3,709; copy number 6: 2,076; copy number 7: 148; copy number 8: 27; copy number 9: 34; copy number 10: 11; copy number 11: 27; copy number 12: 19.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 266 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:850,291–1,523,962, 23 genes, copy number 8–11 (within-gene range 4–11): BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075.
- chr5:2,184,710–6,030,841, 42 genes, copy number 7–12: Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC010266.2, AC010266.1.
- chr5:26,669,346–27,496,994, 9 genes, copy number 10: AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1.
- chr5:28,548,135–28,809,291, 1 gene, copy number 7 (within-gene range 3–7): AC008825.1.
- chr5:28,808,538–29,217,115, 6 genes, copy number 7–9 (within-gene range 3–9): AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3.
- chr5:29,304,305–29,396,095, 1 gene, copy number 9: LINC02064.
- chr5:35,852,695–37,085,852, 25 genes, copy number 7: IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL, KRT18P31, RPS4XP6.
- chr7:38,239,580–38,249,572, 1 gene, copy number 7: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 7: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes, copy number 7 (within-gene range 5–7): TRGV5P, TRGV5, TRGV4.
- chr14:22,066,016–22,190,713, 15 genes, copy number 7: AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr14:22,202,583–22,272,563, 6 genes, copy number 7: TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1.
- chr14:31,025,106–36,235,608, 99 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr14:38,190,983–38,371,338, 4 genes, copy number 8–10 (within-gene range 3–10): AL392023.1, SSTR1, CLEC14A, AL355835.1.
- chr14:43,540,883–43,596,683, 3 genes, copy number 8: KRT8P2, AL358913.1, ARHGAP16P.
- chr14:44,392,531–44,567,467, 4 genes, copy number 7: AL161752.1, LINC02277, FSCB, AL356022.1.
- chr14:45,502,742–47,675,605, 9 genes, copy number 9–11 (within-gene range 6–11): AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L, MDGA2, AL359951.1, RPA2P1, RPL13AP2.

Autosomal genes at a single copy (total copy number 1): 2,126. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
